Surgical pathology report (de-identified scan), TCGA case TCGA-92-7340, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - St. Louis, specimen TCGA-92-7340-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT
FINAL

DIAGNOSIS:

LUNG, RIGHT UPPER LOBE, EXCISION - EPIDERMOID CARCINOMA

LYMPH NODE, HILAR, UPPER LOBE, EXCISION - METASTATIC EPIDERMOID CARCINOMA (6/11)

LYMPH NODE, SUBPLEURAL, UPPER LOBE, EXCISION - NO EVIDENCE OF MALIGNANCY (1/1)

LUNG, RIGHT MIDDLE/LOWER LOBE, EXCISION - CARCINOMA-IN-SITU

LYMPH NODE, HILAR, MIDDLE/LOWER LOBE, EXCISION - NO EVIDENCE OF MALIGNANCY (8/8)

LYMPH NODE, SUBPLEURAL, MIDDLE/LOWER LOBE, EXCISION - NO EVIDENCE OF MALIGNANCY (2/2)

LYMPH NODE, LEVEL 7, EXCISIONAL BIOPSY - NO EVIDENCE OF MALIGNANCY (4/4)

LYMPH NODE, LEVEL 10R, EXCISIONAL BIOPSY - NO EVIDENCE OF MALIGNANCY (4/4)

LYMPH NODE, LEVEL 4R, EXCISIONAL BIOPSY - NO EVIDENCE OF MALIGNANCY (4/4)

LYMPH NODE, LEVEL 2R, EXCISIONAL BIOPSY - NO EVIDENCE OF MALIGNANCY (1/1)

LYMPH NODE, LEVEL 11R, EXCISIONAL BIOPSY - NO EVIDENCE OF MALIGNANCY (2/2)

LYMPH NODE, LEVEL 9, EXCISIONAL BIOPSY - NO EVIDENCE OF MALIGNANCY (1/1)

LYMPH NODE, LEVEL 10R, EXCISIONAL BIOPSY - NO EVIDENCE OF MALIGNANCY (1/1)

LUNG, BRONCHUS, RIGHT UPPER MAIN, INCISIONAL BIOPSY - NO HISTOPATHOLOGIC ABNORMALITY

ARTERY, PULMONARY, INCISIONAL BIOPSY - NO HISTOPATHOLOGIC ABNORMALITY

[page 2 of 4]
[REDACTED]

Intraoperative Consultation:

"Brought to the frozen section area is a 'right upper lobe and right main bronchus,' consisting of a 171 gram, 10 x 10 x 5 cm lobe of lung. Sectioned to show a 3.5 x 3.5 x 3 cm firm, white-yellow mass near the hilum invading the bronchus, though not present at the proximal or distal margins. Tissue taken for tumor bed, [REDACTED] and lung study. Inflated. Rest for permanents," by [REDACTED]

"Brought to the frozen section area is 'right middle and lower lobe,' consisting of a 153 gram, 13 x 11 x 4 cm lobe of lung. Bronchial tissue (not margin) taken for lung study. Inflated. Rest for permanents," [REDACTED]

FS1: Lymph node, level 7, subcarinal, excisional biopsy

- "No evidence of malignancy," by [REDACTED]

FS2: Lymph node, level 10R, excisional biopsy

- "No evidence of malignancy," [REDACTED]

FS3: Lymph node, level 4R, excisional biopsy

- "No evidence of malignancy," [REDACTED]

FS4: Lymph node, level 2R, excisional biopsy

- "Vascular structures, no lymphoid tissue seen," [REDACTED]

FS5: Lymph node, level 11R, excisional biopsy

- "No evidence of malignancy," by [REDACTED]

FS6: Lung, bronchial margin, excision

- "No evidence of malignancy," by [REDACTED]

[REDACTED]

Microscopic Description and Comment:

Sections of the right upper lobe of the lung show moderately differentiated epidermoid carcinoma involving a large bronchus. There is extensive perineural invasion and involvement of several hilar lymph nodes, but the exact number is difficult to determine with only a crude estimate possible. A subpleural lymph node is unremarkable as is the "right main bronchial margin." The material from the right middle and lower lobes show carcinoma-in-situ of the bronchial margin of resection, and two subpleural and eight hilar nodes that are free of tumor; the lung parenchyma is free of tumor. No tumor is found in any of the mediastinal lymph nodes examined, or in the "pulmonary artery proximal margin" [REDACTED]

[REDACTED]

History:

The patient is a [REDACTED]
procedure: Right upper lobectomy.

[REDACTED] nstated race, with epidermoid carcinoma of the lung [REDACTED] Operative

Specimen(s) Received:

A: LYMPH NODE, LEVEL 7 SUBCARINAL
B: LYMPH NODE, 10 R

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

C: LYMPH NODE, 4R
D: LYMPH NODE, 2R
E: LYMPH NODE, 11R
F: LYMPH NODE, LEVEL 9
G: PULMONARY ARTERY, PROXIMAL MARGIN
H: RIGHT MIDDLE AND LOWER LOBE
I: RIGHT MAIN BRONCHIAL MARGIN
J: RIGHT UPPER LOBE AND RIGHT MAIN BRONCHUS
K: LYMPH NODE, 10R

Gross Description:

The specimens are received in eleven formalin-filled containers, each labeled with the patient's name,

The first is labeled "level 7, subcarinal lymph node/FS1." It consists of two yellow-white tissue remnants measuring 1.5 x 1.1 x 0.3 cm in aggregate. Labeled A (FS1). Jar 0.

The second specimen is labeled "10R lymph node/FS2." It consists of four yellow-white tissue remnants measuring 2.1 x 1.7 x 0.2 cm in aggregate. Labeled B (FS2). Jar 0.

The third specimen is labeled "4R lymph node/FS3." It consists of a tissue cassette that holds two yellow-brown tissue remnants measuring 2 x 1.5 x 0.3 cm in aggregate. Labeled C (FS3). Jar 0.

The fourth specimen is labeled "2R lymph node/FS4." It consists of a tissue cassette labeled "FS4" that holds a single yellow-brown tissue remnant measuring 1.2 x 1 x 0.3 cm. Labeled D (FS4). Jar 0.

The fifth specimen is labeled "11R lymph node/FS5." It consists of a tissue cassette labeled "FS5" that holds two black and yellow tissue remnants measuring 1.2 x 1.2 x 0.3 cm in aggregate. Labeled E (FS5). Jar 0.

The sixth specimen is labeled "level 9." It consists of a single gray lymph node measuring 0.4 x 0.2 x 0.2 cm with attached fibroadipose tissue. Labeled F. Jar 0.

The seventh specimen is labeled "pulmonary artery proximal margin." It consists of a segment of artery measuring 1.5 cm length x ~1.3 cm diameter. It is stapled at one end. Both the inner and outer surfaces are smooth without adherent soft tissue or thrombus. Labeled G. Jar 1.

The eighth specimen is labeled "right middle and lower lobe." It consists of a piece of lung with the characteristics described in the intraoperative consultation. Following formalin fixation, the pleura is wrinkled, but smooth, without adhesions or plaques. Following tissue harvest, there is a 0.2 cm missing segment of bronchus located 0.4 cm distal to the margin. Two subpleural lymph nodes measuring 0.7 x 0.3 x 0.3 cm and 0.6 x 0.6 x 0.3 cm are present and unremarkable. In the hilum, there is abundant mucus present in the bronchus. The hilar vessels are unremarkable. Several lymph nodes are dissected from the hilum and measure 0.4 to 1.1 cm, have anthracotic pigment, and are otherwise unremarkable. The lung is sectioned to show tan-gray, spongy tissue without masses or lesions. Labeled H1 - vascular and bronchial margins; H2 - hilar lymph nodes; H3 - subpleural lymph nodes; H4 - right lower lobe; H5 - right middle lobe. Jar 3.

The ninth specimen is labeled "right main bronchial margin/FS6." It consists of a firm, white, ring-shaped tissue remnant measuring 1.5 cm diameter x 0.1 cm length. Labeled I (FS6). Jar 0.

The tenth specimen is labeled "right upper lobe and right main bronchus." It consists of lung with the characteristics described in the intraoperative consultation. Following formalin fixation, the pleura is wrinkled, but smooth, without adhesions or plaques. Following tissue/tumor harvest, there is a 3 x 3 x 2 cm tissue defect in the peripheral parenchyma and a 2 x 1 x 0.4 cm tissue defect in the tumor mass. A single subpleural lymph node measuring 0.5 x 0.4 x 0.2 cm is present and unremarkable. The tumor in the hilum is firm and white-yellow with focal necrosis. It invades the bronchus and is present at the proximal and distal margins. The remainder of the lung parenchyma is brown-purple, spongy, and otherwise unremarkable. Labeled J1 - proximal (single lumen) and distal (bifurcated lumens) bronchial margins; J2 - vascular margins; J3 and J4 - hilar lymph nodes; J5 to J8 - tumor; J9 - subpleural lymph node and underlying unremarkable parenchyma. Jar 2.

The 11th specimen is labeled "10R lymph node." It consists of a single black lymph node measuring 0.9 x 0.6 x 0.3 cm. Labeled K. Jar 0.

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

SYNOPTIC

HISTOPATHOLOGIC TYPE

The histologic classification of the tumor is epidermoid carcinoma, non-keratinizing type

HISTOLOGIC GRADE

The grade of the tumor is moderately differentiated

TUMOR SIZE

The maximum dimension of the tumor is 3.5 cm

VENOUS INVASION

Not seen on routine stained slides

PLEURAL INVOLVEMENT

Pleural involvement is absent

SAMPLED SPECIMEN MARGINS

The sampled surgical margins are involved by tumor (carcinoma-in-situ) at the middle and lower lobe bronchus

PRIMARY TUMOR

T2a

REGIONAL LYMPH NODES

The total number of lymph nodes examined is 39

The total number of metastatically-involved lymph nodes is 6

N1

DISTANT METASTASIS

MX

Source: NCI Genomic Data Commons file c30a18d0-eb94-4432-9025-9a3b638006ce (TCGA-92-7340.EC11729E-F821-4F7B-91C5-0ED2026E5881.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).